Somatic mutation profile of tumor specimen C3L-08159-02 (aliquot CPT0511860006) from CPTAC case C3L-08159, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.3 years (22,764 days).
Specimen C3L-08159-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8de0c033-c716-4407-999a-49bbe33b79b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08159-31 (Blood Derived Normal), aliquot CPT0511840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018913af-9771-46dc-b60c-8beabc4d52f7

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 20, Nonsense Mutation 6, Splice Region 1, Translation Start Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 35/305 reads (11%) | hotspot (GDC flag); catalogued as COSV52665429, COSV52669330, COSV52682693, COSV52815283; called by muse, mutect2, varscan2
- ARHGEF15 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 62/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1242591415, COSV62725357; called by muse, mutect2, varscan2
- ATRNL1 | c.212C>G p.S71W | Missense Mutation (SNP) | VAF 31/684 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as rs782083561, COSV100747097; called by muse, mutect2
- DGKQ | c.1218C>G p.L406= | Splice Region (SNP) | VAF 43/352 reads (12%) | catalogued as rs762650084; called by muse, mutect2, varscan2
- ENPEP | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 54/496 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.228); catalogued as rs146706022; called by muse, mutect2, varscan2
- EXOC3L4 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 92/576 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as rs1206510170; called by muse, mutect2, varscan2
- GAL3ST3 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 59/505 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200393443; called by muse, mutect2, varscan2
- GJD4 | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58702585; called by muse, varscan2
- GLI3 | c.3185C>A p.S1062* | Nonsense Mutation (SNP) | VAF 50/500 reads (10%) | catalogued as COSV67887500; called by muse, mutect2
- HS3ST4 | c.1335A>C p.Q445H | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.981); catalogued as COSV58803837, COSV58808981; called by muse, mutect2
- IQSEC2 | c.2816G>A p.R939H (on ENST00000642864 / NM_001111125.3; = p.R734H on NM_015075.2) | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs782727618; ClinVar: likely benign; called by muse, mutect2
- KIR2DL1 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 15/428 reads (4%) | catalogued as rs1569213241; called by muse, mutect2
- KMT2D | c.8366G>A p.R2789Q | Missense Mutation (SNP) | VAF 33/425 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as rs1208681909, COSV56417455; called by muse, mutect2
- MID2 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53309353; called by muse, mutect2, varscan2
- NLRP2 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 74/669 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs745776240, COSV54759342; called by muse, mutect2, varscan2
- PRPF6 | c.1044A>C p.E348D | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV53866873; called by muse, mutect2
- PTPRD | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1050031711, COSV61936738; called by muse, mutect2
- SHH | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 64/631 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV51918594; called by muse, mutect2
- SLC25A6 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV67317685; called by muse, mutect2
- TMTC1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.089); catalogued as rs778881609; called by muse, mutect2
- TPTE2 | c.1064G>A p.R355Q (on ENST00000400230 / NM_199254.2; = p.R278Q on NM_130785.3) | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555497368, COSV55028143; called by muse, mutect2
- TTN | c.966G>T p.R322S | Missense Mutation (SNP) | VAF 71/380 reads (19%) | PolyPhen benign (0.033); catalogued as rs551244224; called by muse, mutect2, varscan2
- ZNF425 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 21/485 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1253523992, COSV65201093; called by muse, mutect2
- ZNF71 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 151/586 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1384814269; called by muse, mutect2, varscan2
- ACIN1 | c.3240A>C p.K1080N | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CBLL2 | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CCDC180 | c.1464C>G p.H488Q | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CDH4 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP55 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DGKA | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/330 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); called by muse, mutect2
- FAM133B | c.684T>G p.H228Q | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.26); called by muse, mutect2
- FHDC1 | c.2951C>T p.P984L | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- FKBP9 | c.894C>G p.S298R | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); called by muse, mutect2
- FNDC1 | c.2381G>T p.R794M | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2
- GRM1 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HAPLN3 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 50/614 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- HLA-DQA2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 74/631 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- HSF2 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- IGHG3 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 83/458 reads (18%) | called by muse, mutect2, varscan2
- KCNA4 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- KTN1 | c.808A>C p.K270Q | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAV3 | c.5975C>G p.S1992C (on ENST00000397909 / NM_001024383.2; = p.S1970C on NM_014903.6) | Missense Mutation (SNP) | VAF 22/369 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2
- NEXMIF | c.1080T>A p.D360E | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.141); called by muse, mutect2
- OR1N2 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.047); called by muse, mutect2
- RNF170 | c.359G>A p.W120* | Nonsense Mutation (SNP) | VAF 42/373 reads (11%) | called by muse, mutect2
- RPL10L | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SARM1 | c.1523G>A p.C508Y | Missense Mutation (SNP) | VAF 17/512 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SCN11A | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- SORCS3 | c.3582A>C p.K1194N | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2
- SRRM2 | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 19/631 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- TERF2IP | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, varscan2
- TMEM185A | c.454_455del p.Q152Vfs*76 | Frame Shift Del (DEL) | VAF 16/184 reads (9%) | called by mutect2, pindel
- TTN | c.38051T>G p.L12684R (on ENST00000591111; = p.L5260R on NM_003319.4) | Missense Mutation (SNP) | VAF 56/292 reads (19%) | PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- XPOT | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2
- ZDHHC22 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 76/467 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ACOX1 | c.1425G>T p.V475= | Silent (SNP) | VAF 55/376 reads (15%) | called by muse, mutect2, varscan2
- ADAM12 | c.1272C>G p.G424= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- BTK | c.1275C>T p.Y425= | Silent (SNP) | VAF 57/289 reads (20%) | catalogued as rs128621199, CM940195; called by muse, mutect2, varscan2
- COPB1 | c.2565T>G p.V855= | Silent (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- DNAH17 | c.12414C>T p.H4138= | Silent (SNP) | VAF 44/271 reads (16%) | catalogued as rs557732049; called by muse, mutect2, varscan2
- GJD4 | c.216G>C p.V72= | Silent (SNP) | VAF 54/450 reads (12%) | called by muse, varscan2
- HEPACAM | c.1221C>T p.D407= | Silent (SNP) | VAF 54/389 reads (14%) | catalogued as COSV53433335; called by muse, mutect2, varscan2
- LAMA1 | c.6696A>G p.K2232= | Silent (SNP) | VAF 44/301 reads (15%) | called by muse, mutect2, varscan2
- MEX3A | c.354C>G p.L118= | Silent (SNP) | VAF 13/332 reads (4%) | called by muse, mutect2
- MYOM2 | c.2790C>T p.F930= | Silent (SNP) | VAF 48/482 reads (10%) | catalogued as rs555520987, COSV50707851; called by muse, mutect2, varscan2
- NEUROD4 | c.12T>G p.T4= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV54471636; called by muse, mutect2
- PGR | c.2761T>C p.L921= | Silent (SNP) | VAF 27/257 reads (11%) | catalogued as rs1472757318; called by muse, mutect2, varscan2
- RGMA | c.1179C>T p.A393= | Silent (SNP) | VAF 59/512 reads (12%) | catalogued as rs370807777; called by muse, mutect2, varscan2
- SLC16A7 | c.1254C>T p.S418= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as rs952553480, COSV99676796; called by muse, mutect2
- SLC25A51 | c.393A>G p.T131= | Silent (SNP) | VAF 40/394 reads (10%) | called by muse, mutect2, varscan2
- SMTNL2 | c.993G>A p.G331= (on ENST00000389313 / NM_001114974.2; = p.G187= on NM_198501.3) | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as rs1490496085; called by muse, mutect2
- SRGAP3 | c.3186G>A p.P1062= | Silent (SNP) | VAF 56/522 reads (11%) | catalogued as rs771932247; called by muse, varscan2
- TENT4A | c.459C>T p.A153= | Silent (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- UBR7 | c.588T>G p.A196= | Silent (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- UPP1 | c.780C>G p.A260= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- ZNF665 | c.-53-9194G>C | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
